Surgical pathology report (de-identified scan), TCGA case TCGA-CF-A9FM, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site ILSBio, specimen TCGA-CF-A9FM-01A (Primary Tumor).

[page 1 of 4]
Clinical Case Report

(For Collection of Cancerous Tissue)

ICD-3

*Carcinoma papillary urothelial
cell 8/30/13
Carcinoma papillary transitional
cell 8/30/13
Date 4/30/14 NOS C67.9*

Informed Consent

I personally informed this patient that a specimen(s) would be collected to be used for research purposes. I reviewed the **RESEARCH SUBJECT INFORMATION AND CONSENT FORM** with the patient and answered any questions the patient had. The patient then signed the consent form as a free and voluntary act. A copy of this informed consent document will be retained at our institution.

Name of Physician or Study Coordinator

Signature

Date

Clinical Information

GENERAL INFORMATION				
Date of Birth (mm/dd/yyyy)	Height	Marital Status	Race	Temperature
		☐ Single ☒ Married	Vietnamese	
Gender	Weight	☐ Divorced ☐ Widow	Blood Pressure	Heart Rate
☒ Male ☐ Female				

HISTORY OF PRESENT ILLNESS	
Chief Complaints:	Hematuria
Symptoms:	Patient had continuous hematuria for [blank], and had blood in stools.
Clinical Findings:	Soft belly, no peripheral lymph nodes.
Performance Scale (Karnofsky Score): ☐ 100 Asymptomatic ☐ 80-90 Symptomatic but Fully Ambulatory ☐ 60-70 Symptomatic, in bed less than 50% of day ☐ 40-50 Symptomatic, in bed more than 50% of day, but not bed ridden ☐ 20-30 Bed Ridden	

CURRENT MEDICATIONS				
Drug	Dose	Route	Frequency	Date (mm/dd/yyyy)
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 2 of 4]
PAST MEDICAL HISTORY			
Diagnosis/Disease/Disorder/Injury	Diagnosis Date	Treatment	Status
No			

OB/GYN HISTORY		
Menopausal Status	Date of First Menses	# of Pregnancies
☐ Pre-menopausal		
☐ Peri-Menopausal	Date of Last Menses	# of Live Births
☐ Post-menopausal		
Birth Control: ☐ Condom ☐ Oral Contraceptive ☐ IUD ☐ Other: _____		☐ Hormone Replacement Therapy: _____

SOCIAL HISTORY				
Occupation:		Environmental Hazards:		
Smoking History				
Current Status	TYPE	Packs/day	Duration	When Quit
☒ YES ☐ NO	N/A		(yrs)	(yr)
Alcohol Consumption				
Current Status	TYPE	Drinks/day	Duration	When Quit
☒ YES ☐ NO	N/A		(yrs)	(yr)
Drug Use				
Current Status	TYPE	Frequency	Duration	When Quit
☐ YES ☒ NO			(yrs)	(yr)

FAMILY MEDICAL HISTORY		
Relative	Diagnosis	Age of Diagnosis
	No	

LAB DATA						
Test	Result	Date	Test	Result	Date	
HIV	☒ Negative ☐ Positive: _____		CEA	☐ Negative ☐ Positive: _____		
Hep B	☒ Negative ☐ Positive: _____		CA 15-3	☐ Negative ☐ Positive: _____		
Hep C	☐ Negative ☐ Positive: _____		CA 19-9	☐ Negative ☐ Positive: _____		
AFP	☐ Negative ☐ Positive: _____		PSA	☐ Negative ☐ Positive: _____		
Other:	☐ Negative ☐ Positive: _____		Other:	☐ Negative ☐ Positive: _____		
B/T Cell Markers:						

[page 3 of 4]
DIAGNOSTIC STUDIES		
Study	Results	Date
Ultrasound		
X-Ray	Normal chest X-ray	
CT	Suspected bladder tumor, invades fat tissues	
Endoscopy	Tumor on the posterior wall of bladder, >5cm in dimension	
MRI		
Biopsy	Transitional cell carcinoma, low grade	

CLINICAL DIAGNOSIS		
Preoperative Clinical Diagnosis		
bladder cancer		
Location of Suspected Involved Lymph Nodes	Location of Suspected Distant Metastasis	
Pelvis		
Clinical Staging		Date of Diagnosis
T ₃ N ₁ M ₀	Stage: IV	

Treatment Information

SURGICAL TREATMENT			
Procedure			Date of Procedure
Cystectomy			
Primary Tumor			
Organ	Detailed Location		Size
Bladder			4.5 x 4 x cm
Extension of Tumor			
Muscle			
Lymph Nodes			
Description	Location of Lymph Nodes		# of Lymph Nodes
Palpable, Non-Dissected Lymph Nodes	Pelvis		10
Dissected Lymph Nodes			
Distant Metastasis			
Organ	Detailed Location		Size
Surgical Staging			
T ₃	N ₁	M ₀	Stage: IV

NEOADJUVANT THERAPY (Chemo, Radiation, Immuno, Hormonal, or Molecular)				
Drug/Treatment	Dose	Route	Frequency	Date (mm/dd/yyyy)
N.A				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /
				/ / To / /

[page 4 of 4]
Consolidated Pathology Diagnosis

ID#: _____

Histological Pattern											
Cell Distribution			+	-	Structural Pattern			+	-		
Diffuse				✓	Streaming						
Mosaic			✓		Storiform						
Necrosis				✓	Fibrosis						
Lymphocytic Infiltration			✓		Palisading						
Vascular Invasion				✓	Cystic Degeneration						
Clusterized			✓		Bleeding						
Alveolar Formation				✓	Myxoid Change						
Indian File				✓	Psammoma/Calcification						

Cellular Differentiation											
Squamous	+	-	Adenomatous	+	-	Sarcomatous	+	-	Lymphomatous	+	-
Squamoid Cell	✓		Glandular cell			Round Cell			Large Cell		
Spindle Cell	✓		Cell Stratification			Fibroblast			Small Cell		
Keratin			Secretion			Osteoblast			RS Cell/RS Like		
Desmosome			Intracyt. Vacuole			Lipoblast			Inflam. Cell		
Pearl			Gland formation			Myoblast			Plasma Cell		

Cellular Differentiation: ☐ Well ☒ Moderate ☐ Poor

Nuclear Appearance				
Nuclear Atypia:	0	I	II	III
Aniso Nucleosis			✓	
Hyperchromatism		✓		
Nucleolar Prominent		✓		
Multinucleated Giant Cell		✓		
Mitotic Activity			✓	
Nuclear Grade:			✓	

Final Pathology Report

Histological Diagnosis: Papillary Transitional cell carcinoma Grade: 2

Comments:

Director, Research Pathology

Date

INTEGRATED REPORT OF FINDINGS BY COLLABORATORS AND

PATHOLOGISTS -

Source: NCI Genomic Data Commons file cebd59bf-329f-4711-8e33-d8014ac2a9d0 (TCGA-CF-A9FM.D8D401F9-26CE-4A36-9A01-2EC6A02BC35B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).